Gene-level copy-number profile of tumor specimen TCGA-EK-A2GZ-01A from TCGA case TCGA-EK-A2GZ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 64.6 years (23,599 days).
Specimen TCGA-EK-A2GZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.684386f0-695f-4dae-b8a0-490bbdab5293.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EK-A2GZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d9c322ff-d8ce-401a-858b-8d016bdbf132

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 417; copy number 2: 3,144; copy number 3: 18,877; copy number 4: 23,470; copy number 5: 7,800; copy number 6: 589; copy number 7: 1,309; copy number 8: 2,843; copy number 10: 100; copy number 11: 46; copy number 12: 85; copy number 13: 1,064; copy number 14: 4; copy number 15: 32; copy number 25: 21; copy number 43: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EK-A2GZ-01A-11D-A17U-01): tumor purity 0.58, ploidy 2.16, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,365 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:173,575,110–177,392,697, 99 genes, copy number 11–25 (broad region; genes not listed).
- chr2:214,931,542–218,842,065, 100 genes, copy number 10 (within-gene range 7–10) (broad region; genes not listed).
- chr3:137,518,134–198,222,513, 1,064 genes, copy number 13 (broad region; genes not listed).
- chr4:55,157,877–55,798,731, 17 genes, copy number 14–43: AC021220.2, RN7SL822P, AC021220.1, RNU6-746P, LRRC34P2, SRD5A3, FCF1P8, SRD5A3-AS1, AC069200.1, TMEM165, Y_RNA, CLOCK, Y_RNA, AC024243.1, PDCL2, NMU, RNU6-276P.
- chr7:70,972–3,302,452, 84 genes, copy number 12 (broad region; genes not listed).
- chr7:3,337,889–3,338,601, 1 gene, copy number 12: AC092427.1.

Autosomal genes at a single copy (total copy number 1): 417. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
